Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8I5, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8I5-01A (Primary Tumor).

[page 1 of 4]
(178.0cm 97.9kg BSA: 2.2m²)

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT NEUROVASCULAR BUNDLE BASE:
Nerve and ganglion segments and fibromuscular tissue, no morphologic evidence of malignancy.
- (B) ANTERIOR APEX:
Prostatic parenchyma, no morphologic evidence of malignancy.
- (C) POSTERIOR APEX:
Skeletal and smooth muscle, no prostatic glands identified.
No morphologic evidence of malignancy.
- (D) RIGHT PELVIC LYMPH NODES:
Four lymph nodes, no morphologic evidence of malignancy.
- (E) LEFT PELVIC LYMPH NODES:
Two lymph nodes, no morphologic evidence of malignancy.
- (F) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

Entire report and diagnosis completed by

*USE ICD-O-3
Adenocarcinoma, acinar 8140/3
Adenocarcinoma, NOS 8140/3
Site Prostate NOS C61.9
J 11/24/13*

GROSS DESCRIPTION

- (A) LEFT NEUROVASCULAR BUNDLE BASE, BIOPSY - A tan-pink tissue fragment (0.3 cm) is entirely frozen for intraoperative consultation: A.
*FS/DX: NEGATIVE FOR TUMOR.
- (B) ANTERIOR APEX - A tan-pink tissue fragment (1.0 cm) is entirely frozen for intraoperative consultation: B.
*FS/DX: UNORIENTED, SURGICAL MARGIN - NEGATIVE FOR TUMOR.
- (C) POSTERIOR APEX - A tan-pink tissue fragment (0.3 cm) is entirely frozen for intraoperative consultation: C.
*FS/DX: UNORIENTED, SURGICAL MARGIN - NEGATIVE FOR TUMOR.
- (D) RIGHT PELVIC LYMPH NODE - Four lymph nodes (0.2 to 5.5 cm) within a fragment of adipose tissue (6.0 x 1.5 x 1.0 cm) are entirely submitted: D1, two lymph nodes; D2, one lymph node; D3-D5, one lymph node.
- (E) LEFT PELVIC LYMPH NODE - Two lymph nodes (1.8 and 4.5 cm) within a fragment of adipose tissue (5.0 x 2.0 x 1.0 cm) are entirely submitted: E1, one lymph node; E2-E4, one lymph node.
- (F) PROSTATE AND SEMINAL VESICLES - Supplemental report to follow.

CLINICAL HISTORY

Adenocarcinoma, prostate.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

. These tests have not been

Released by:

[page 2 of 4]
[REDACTED] (178.0cm 97.9kg BSA: 2.2m²)

Specimen Date/Time:

Start of ADDENDUM

[page 3 of 4]
(178.0cm 97.9kg BSA: 2.2m²)

Specimen Date/Time:

ADDENDUM

Addendum completed by

DIAGNOSIS

- (F) PROSTATE AND SEMINAL VESICLES:
PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (3+4). (SEE COMMENT)
TUMOR CONFINED TO THE PROSTATE.
Margins of resection free of tumor.
Right and left seminal vesicles, no tumor present.
Segment of right and left vasa deferentia, no tumor present.

Entire report and diagnosis completed by

COMMENT

The prostate gland contains three separate foci of prostatic adenocarcinoma, one in the transition zone and two in the peripheral zone. The dominant tumor focus is located in the left and right transition zone. This tumor focus measures 3.0 x 0.8 cm in the largest cross sectional dimension and it is present in three cross sections and extensively in the apex and base regions. The second largest tumor focus is located in the right lateral, right posterolateral, and right posterior peripheral zone. This tumor focus measures 2.5 x 1.0 cm in the largest cross sectional dimension and it is present in three cross sections and extensively in the apex and base regions. The third tumor focus is located in the left anterolateral, left lateral, left posterolateral, and left posterior peripheral zone. This tumor focus measures 2.5 x 0.4 cm in the largest cross sectional dimension and it is present in three cross sections and focally in the base region. All tumor foci are confined to the prostate. The margins of resection are free of tumor.

GROSS DESCRIPTION

(F) PROSTATE AND SEMINAL VESICLES - A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (4.5 x 3.5 x 4.5 cm, 39 grams, post-fixation) has the usual shape. The soft tissue present along the right posterolateral aspect of the prostate appears more abundant than along the left side. A nodule is palpated in the right base region. Serial cross sections after fixation demonstrate a firm area consistent with tumor in the right peripheral zone extending from the first to the third cross sections of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor. Also included in the container is a detached portion of tissue consistent with seminal vesicle (3.0 x 1.8 x 0.7 cm).

SECTION CODE: F1, F2, detached portion of tissue; F3, F4, base of right seminal vesicle and right vas deferens; F5, F6, base of left seminal vesicle and left vas deferens; F7, F8, prostatic base right border; F9-F11, prostatic base right posterior border; F12, F16, prostatic base central portion; F17, prostatic base left border; F18, F19, prostatic base left posterior border; F20, F21, apex anterior; F22, apex left; F23, F25, apex posterior; F26, apex right; F27-F40, sections of the three cross sections of the

[page 4 of 4]
[REDACTED] (178.0cm 97.9kg BSA: 2.2m²)

Specimen Date/Time:

prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black.

SNOMED CODES

Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 3a974057-f00e-45f5-afe6-ae7e38f9bdb6 (TCGA-KK-A8I5.CF19D931-B8BE-4978-8C08-081744230305.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).